Gene-level copy-number profile of tumor specimen HTMCP-03-06-02396-01A from CGCI case HTMCP-03-06-02396, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 47.4 years (17,324 days).
Specimen HTMCP-03-06-02396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f7639cd6-731e-4f09-b6bd-3403050f511c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02396-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/709addf7-f4e4-46e8-a0b4-61921f1e4ee2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 3,275; copy number 2: 22,197; copy number 3: 21,248; copy number 4: 5,881; copy number 5: 4,444; copy number 6: 592; copy number 7: 324; copy number 8: 301; copy number 10: 47; copy number 13: 34.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr5:69,875,271–70,860,579, 18 genes: GUSBP13, AC131392.1, CDH12P2, SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1.
- chr22:18,501,794–18,638,405, 12 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,693 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,474,790, 44 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1.
- chr2:52,474,073–52,961,452, 8 genes, copy number 5: GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:92,006,680–94,604,573, 4 genes, copy number 5: AC128677.1, IGKV1OR2-2, AL845331.2, AL845331.1.
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 5–6 (broad region; genes not listed).
- chr5:710,355–1,246,189, 17 genes, copy number 5–6: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18.
- chr5:7,396,138–16,617,058, 135 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:17,345,616–40,269,719, 303 genes, copy number 5 (broad region; genes not listed).
- chr5:41,142,116–45,895,970, 71 genes, copy number 5 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,335,514, 14 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,626,649–142,793,368, 27 genes, copy number 5: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 5: TRBC2.
- chr14:18,333,726–19,883,932, 78 genes, copy number 5–6 (broad region; genes not listed).
- chr14:19,920,582–20,357,904, 32 genes, copy number 5–6: OR4K5, OR4K1, OR4K16P, OR4K15, OR4Q2, OR4K14, OR4K13, OR4U1P, OR4L1, RNA5SP380, OR4T1P, OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1.
- chr14:21,768,489–22,520,031, 101 genes, copy number 6–13 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 13: TRAC.
- chr14:31,025,106–39,388,513, 155 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr14:40,954,693–81,743,749, 787 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:27,638,483–45,370,918, 728 genes, copy number 5–10 (broad region; genes not listed).
- chr20:87,250–8,968,360, 212 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:9,537,370–9,839,076, 2 genes, copy number 5 (within-gene range 4–5): PAK5, AL353612.2.
- chr20:9,835,556–64,327,972, 1,179 genes, copy number 5–7 (broad region; genes not listed).
- chr22:29,788,609–30,627,271, 40 genes, copy number 5–8: ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2.

Autosomal genes at a single copy (total copy number 1): 2,644. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
